Surgical pathology report (de-identified scan), TCGA case TCGA-69-7980, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-7980-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] F

SPECIMEN SUBMITTED:

Part A: RIGHT LOWER LOBE WEDGE

Part B: RIGHT UPPER LOBE

Part C: #4

Part D: #7

Part E: #11

Part F: 10R

Final Diagnosis

1. Right lung, lower lobe, wedge excision (A) - Lymph nodes negative for neoplasm.
2. Right lung, upper lobe, lobectomy (B) - Adenocarcinoma, lipoidic pattern (see comment).
3. Lymph nodes, #4, #7, #11, 10R (C-F) - Lymph nodes, negative for neoplasm.

Diagnosis Comment:

Tumor Location: Right upper lobe

Tumor Size: 2.5 cm in greatest dimension.

Vascular Invasion: Negative.

Lymphatic Invasion: Negative

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): T1b N0 M0 (Stage IIA)

Intraoperative Diagnosis:

- A. A1-A2 two intraparenchymal lymph nodes, negative for tumor

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis:

RUL MASS

Gross Description:

A. Received fresh labeled "right lower lobe wedge" is a segment of lung measuring 8 x 2 x 1.5 cm. There is a staple line measuring 8 cm. The specimen weighs 4.1 grams. There are two ovoid nodules within the specimen. Nodule #1 measures 0.3 x 0.3 x 0.2 cm and extends to 0.3 cm from the cut margin. Nodule #2 measures 0.5 x 0.5 x 0.4 cm and extends to 0.2 cm from the cut margin. Sections are submitted as follows: FSA1 nodule #1 representative section, FSA2 nodule #2 representative section, A3 remainder of nodule #1, A4 remainder of nodule #2, A5-A7 remainder of specimen entirely submitted.

B. The specimen is received fresh at the surgical desk from the frozen bench labeled "right upper lobe" and consists of a 150.7 gram, 14.5 x 10 x 3 cm right upper lobe lobectomy with an attached 0.3 cm length of bronchial stump. A 2.5 x 2.2 x 1.8 cm tumor abuts the pleural surface and lies adjacent to a pleural thickening measuring 3 x 3 x 0.9 cm. The tumor is tan-white with an irregular border. The remainder of the parenchyma is grossly unremarkable. Sections are submitted as follows: B1 frozen section of bronchial margin, B2 vascular margins, B3-B4 tumor with pleura, B5 tumor with bronchus, B6-B7 pleural thickening, B8 uninvolved lung parenchyma, B9 four lymph nodes totally submitted.

C. Received fresh are multiple tan-black nodules resembling lymph nodes aggregating to 2.0 x 1.0 x 0.3 cm. Totally submitted in one cassette.

D. Received fresh are multiple tan-black nodules resembling lymph nodes aggregating to 3.0 x 2.0 x 1.1 cm. Totally submitted in two cassettes.

E. Received fresh are multiple tan-black nodules resembling lymph nodes aggregating to 2.0 x 1.2 x 0.4 cm. Totally submitted in one cassette.

F. Received fresh are multiple tan-gray nodules resembling lymph nodes aggregating to 0.5 x 0.4 x 0.3 cm. Totally submitted in one cassette.

Source: NCI Genomic Data Commons file bc663057-6a9a-4621-8312-1c01be876b7a (TCGA-69-7980.A4A32CF5-43B8-4387-9873-D90F7000B134.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).